Somatic mutation profile of tumor specimen TCGA-DD-AACT-01A (aliquot TCGA-DD-AACT-01A-11D-A40R-10) from TCGA case TCGA-DD-AACT, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 69.2 years (25,292 days).
Specimen TCGA-DD-AACT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dca55bb4-2fcd-4e0b-a93b-66a84c3e0342.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACT-10A (Blood Derived Normal), aliquot TCGA-DD-AACT-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6abb1206-ace8-4e26-a895-2ffd688f5bd7

The open-access MAF lists 225 somatic variants for this specimen: 165 protein-altering or splice-affecting, 55 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 55, Nonsense Mutation 11, Splice Site 10, Frame Shift Del 7, RNA 2, Intron 2, Nonstop Mutation 1, 3'Flank 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS2 | c.2618A>G p.E873G | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99771188; called by muse, mutect2
- ABCA9 | c.3656T>G p.I1219S | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV100382549; called by muse, mutect2, varscan2
- AHNAK | c.11246A>T p.D3749V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99945366; called by muse, mutect2, varscan2
- AL669918.1 | c.2257A>T p.T753S | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.253); catalogued as rs775119133, COSV101441034; called by muse, mutect2, varscan2
- ALMS1 | c.7296A>T p.L2432F | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV100040978; called by muse, mutect2, varscan2
- ANKAR | c.4184T>C p.I1395T | Missense Mutation (SNP) | VAF 19/692 reads (3%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.011); catalogued as COSV99853826; called by muse, mutect2
- ATAD2 | c.640-2A>T p.X214_splice | Splice Site (SNP) | VAF 60/116 reads (52%) | catalogued as COSV99783985; called by muse, mutect2, varscan2
- AWAT2 | c.31A>T p.T11S | Missense Mutation (SNP) | VAF 118/330 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99339523; called by muse, mutect2, varscan2
- BBS2 | c.431T>A p.L144Q | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99802037; called by muse, mutect2, varscan2
- C20orf204 | c.286A>G p.S96G | Missense Mutation (SNP) | VAF 138/320 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as rs1237046066, COSV99411177; called by muse, mutect2, varscan2
- CACNA1E | c.6856C>T p.R2286W (on ENST00000367573 / NM_001205293.3; = p.R2243W on NM_000721.4) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as rs762766720, COSV62391040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALCOCO1 | c.1978A>T p.K660* | Nonsense Mutation (SNP) | VAF 42/149 reads (28%) | catalogued as COSV100017140; called by muse, varscan2
- CASKIN1 | c.1262A>T p.Q421L | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100623781; called by muse, mutect2, varscan2
- CCDC171 | c.2344A>T p.K782* | Nonsense Mutation (SNP) | VAF 58/190 reads (31%) | catalogued as COSV99899767; called by muse, mutect2, varscan2
- CEP250 | c.6002T>A p.L2001Q | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100698717; called by muse, mutect2, varscan2
- CFAP100 | c.545A>T p.E182V | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100729048; called by muse, mutect2, varscan2
- CHRDL1 | c.677G>A p.R226Q (on ENST00000372045; = p.R232Q on NM_145234.4) | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.968); catalogued as rs141240795, COSV54323868, COSV54325580; called by muse, mutect2, varscan2
- CHRNA2 | c.964T>A p.S322T | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99531856; called by muse, mutect2, varscan2
- CLGN | c.626A>G p.H209R | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100346350; called by muse, mutect2, varscan2
- CMTM6 | c.125A>T p.K42M | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99230145; called by muse, mutect2, varscan2
- CMTR1 | c.281T>A p.L94H | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100990848; called by muse, mutect2, varscan2
- COL16A1 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 14/158 reads (9%) | catalogued as COSV99593436; called by muse, mutect2
- COL1A1 | c.395A>T p.D132V | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99866279; called by muse, mutect2, varscan2
- COL4A5 | c.2947T>A p.Y983N | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as CD120796, COSV100086332; called by muse, mutect2, varscan2
- COL6A2 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55998772; called by muse, mutect2, varscan2
- COQ6 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as rs879576557, COSV99473710; called by muse, mutect2, varscan2
- CPSF1 | c.2073+1G>A p.X691_splice | Splice Site (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100450145; called by muse, mutect2, varscan2
- DBX2 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60340379; called by muse, mutect2, varscan2
- DDB2 | c.697A>G p.K233E | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV99921406; called by muse, mutect2, varscan2
- DEFA3 | c.83A>T p.E28V | Missense Mutation (SNP) | VAF 38/400 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100590597; called by muse, mutect2, varscan2
- DICER1 | c.1067A>T p.H356L | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.678); catalogued as COSV100601709; called by muse, mutect2, varscan2
- DNAH2 | c.5303A>T p.E1768V | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101208959; called by muse, mutect2, varscan2
- EIF2AK3 | c.1411A>G p.I471V | Missense Mutation (SNP) | VAF 179/761 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs764107317, COSV100303359; called by muse, mutect2, varscan2
- EMCN | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99597760; called by muse, mutect2, varscan2
- FAM131B | c.20T>A p.L7Q | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV101281733; called by muse, mutect2, varscan2
- FAT3 | c.11819G>A p.R3940Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as COSV53191619; called by muse, mutect2, varscan2
- FBXO8 | c.478A>T p.K160* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | catalogued as COSV101183614; called by muse, mutect2, varscan2
- FCRLB | c.949A>T p.R317* | Nonsense Mutation (SNP) | VAF 148/233 reads (64%) | catalogued as COSV100396063; called by muse, mutect2, varscan2
- FMO1 | c.263T>A p.L88Q | Missense Mutation (SNP) | VAF 84/143 reads (59%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.988); catalogued as COSV100707682; called by muse, mutect2, varscan2
- FOXP3 | c.335A>T p.H112L | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV100873072; called by muse, mutect2
- GATA2 | c.230-2A>T p.X77_splice | Splice Site (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100350824; called by muse, mutect2, varscan2
- GATA6 | c.401C>G p.A134G | Missense Mutation (SNP) | VAF 255/961 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.135); catalogued as COSV99332861; called by muse, mutect2, varscan2
- GIN1 | c.1285A>T p.S429C | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.319); catalogued as COSV101204264; called by muse, mutect2, varscan2
- GPAT3 | c.779G>T p.R260I | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100022681; called by muse, mutect2, varscan2
- GRK3 | c.827-2A>C p.X276_splice | Splice Site (SNP) | VAF 20/71 reads (28%) | catalogued as COSV100151010; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.644); catalogued as rs147281768; called by muse, mutect2, varscan2
- IFIT3 | c.914A>T p.E305V | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99259703; called by muse, mutect2, varscan2
- IGSF3 | c.3242A>T p.H1081L (on ENST00000369486 / NM_001007237.3; = p.H1101L on NM_001542.4) | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1440941034, COSV100604064; called by muse, mutect2, varscan2
- ILKAP | c.1064G>C p.G355A | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as COSV54520487, COSV99610846; called by muse, mutect2, varscan2
- IRGQ | c.1847T>A p.L616Q | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100338040; called by muse, mutect2, varscan2
- ITGAM | c.2323A>T p.N775Y (on ENST00000648685 / NM_001145808.2; = p.N774Y on NM_000632.4) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.373); catalogued as COSV99791702; called by muse, mutect2, varscan2
- JAK3 | c.346C>A p.H116N | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.093); catalogued as COSV101512867; called by muse, mutect2, varscan2
- KATNA1 | c.44A>T p.E15V | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100167600; called by muse, mutect2, varscan2
- KATNB1 | c.591T>G p.F197L | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV101109904; called by muse, mutect2, varscan2
- KCNH2 | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 81/198 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs199473495, CM022800, COSV100058976; ClinVar: not provided; called by muse, mutect2, varscan2
- KCNJ10 | c.752T>C p.L251P | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV100927854; called by muse, mutect2, varscan2
- KCNT1 | c.446T>C p.L149P (on ENST00000488444; = p.L168P on NM_020822.3) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99704860; called by muse, mutect2, varscan2
- KIFAP3 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 106/169 reads (63%) | catalogued as COSV100846683; called by muse, mutect2, varscan2
- KIRREL2 | c.907A>C p.S303R | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99383483; called by muse, mutect2, varscan2
- KRTAP13-4 | c.86T>A p.L29Q | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV100481703; called by muse, mutect2, varscan2
- LARS1 | c.2271A>T p.E757D (on ENST00000394434 / NM_020117.11; = p.E730D on NM_016460.3) | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.099); catalogued as COSV99198462; called by muse, mutect2, varscan2
- LAYN | c.849G>T p.Q283H (on ENST00000375615 / NM_001258390.1; = p.Q275H on NM_178834.5) | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100986152; called by muse, mutect2, varscan2
- LCOR | c.1349A>T p.K450M | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99616547; called by muse, mutect2, varscan2
- LHCGR | c.1354C>A p.L452I | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99683085; called by muse, mutect2, varscan2
- LRP1 | c.8318C>T p.T2773M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1411682069, COSV99674175; called by muse, mutect2, varscan2
- LRRC40 | c.1112A>T p.D371V | Missense Mutation (SNP) | VAF 110/400 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV100918681; called by muse, varscan2
- LTK | c.560A>T p.E187V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV99778521; called by muse, mutect2, varscan2
- LVRN | c.1646T>C p.M549T | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV100773310; called by muse, mutect2, varscan2
- MAML3 | c.3101T>A p.L1034H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101558313; called by muse, mutect2, varscan2
- MCM10 | c.2349C>A p.C783* (on ENST00000484800 / NM_182751.3; = p.C782* on NM_018518.5) | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as rs1431767040, COSV101097884, COSV66332914; called by muse, mutect2, varscan2
- MED24 | c.1613A>T p.K538M | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100672930; called by muse, mutect2, varscan2
- MFSD2A | c.751A>G p.T251A (on ENST00000372809 / NM_001136493.3; = p.T238A on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.297); catalogued as COSV100861599; called by muse, mutect2
- MYCBP2 | c.8980A>T p.R2994* (on ENST00000357337; = p.R3032* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 28/105 reads (27%) | catalogued as COSV100629076; called by muse, mutect2, varscan2
- MYH8 | c.1439G>T p.C480F | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101238108; called by muse, mutect2, varscan2
- MYT1L | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.863); catalogued as COSV101218523; called by muse, mutect2, varscan2
- NNT | c.2998A>G p.T1000A | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); catalogued as COSV99238328; called by muse, mutect2, varscan2
- NOD2 | c.2267G>T p.R756L | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs375713299, COSV100318034; called by muse, mutect2, varscan2
- NOMO3 | c.1448C>T p.T483I | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV99530624; called by muse, mutect2, varscan2
- NOS1 | c.4060T>A p.C1354S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV100499956; called by muse, mutect2, varscan2
- NPAP1 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.728); catalogued as rs1289511015, COSV61508546, COSV61510658; called by muse, mutect2, varscan2
- NUP133 | c.3212T>C p.L1071P | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99772520; called by muse, mutect2, varscan2
- NUP160 | c.2776-2A>G p.X926_splice | Splice Site (SNP) | VAF 34/103 reads (33%) | catalogued as rs1249233039, COSV101021246; called by muse, mutect2, varscan2
- NUS1 | c.682A>T p.S228C | Missense Mutation (SNP) | VAF 169/399 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as COSV100874903; called by muse, varscan2
- NUTM1 | c.1120A>T p.I374F | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100148804; called by muse, mutect2, varscan2
- OBSL1 | c.3134G>A p.R1045H | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs750084343, COSV54707421, COSV99216035; called by muse, mutect2, varscan2
- OPALIN | c.46T>A p.S16T | Missense Mutation (SNP) | VAF 197/634 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.187); catalogued as COSV100959561; called by muse, mutect2, varscan2
- OR1M1 | c.113T>A p.M38K | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101447533; called by muse, mutect2, varscan2
- OR5AC2 | c.611T>C p.F204S | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV100684273; called by muse, mutect2, varscan2
- OTOL1 | c.1075C>A p.P359T | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1043177892, COSV100019806, COSV60006681; called by muse, mutect2, varscan2
- PAK1 | c.499A>T p.T167S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99582879; called by muse, mutect2
- PAK1 | c.497A>T p.E166V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV99582881; called by muse, mutect2
- PCDHB12 | c.1195A>G p.N399D | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.609); catalogued as COSV99506630; called by muse, mutect2, varscan2
- PDS5B | c.3332A>G p.Y1111C | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100220407; called by muse, mutect2, varscan2
- PIF1 | c.932T>A p.V311E | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99164719; called by muse, mutect2, varscan2
- PIK3CA | c.256A>T p.T86S | Missense Mutation (SNP) | VAF 71/268 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV99833223; called by muse, mutect2, varscan2
- PKHD1 | c.9167A>T p.Q3056L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV100580907; called by muse, mutect2, varscan2
- PLEKHH2 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99174286; called by muse, mutect2, varscan2
- PLXNA2 | c.4501-2A>T p.X1501_splice | Splice Site (SNP) | VAF 32/189 reads (17%) | catalogued as COSV100885061; called by muse, mutect2, varscan2
- PODNL1 | c.318A>G p.E106= | Splice Region (SNP) | VAF 20/65 reads (31%) | catalogued as COSV99582745; called by muse, mutect2, varscan2
- PREPL | c.1352A>C p.K451T | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV99575887; called by muse, mutect2, varscan2
- PRF1 | c.724T>A p.C242S | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100942512; called by muse, mutect2, varscan2
- PRKCB | c.776T>C p.L259S | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV100332004; called by muse, mutect2, varscan2
- PTPN12 | c.721A>G p.I241V | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV99950032; called by muse, mutect2, varscan2
- PTPN14 | c.3290A>G p.Q1097R | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100872298; called by muse, mutect2, varscan2
- PTPN22 | c.2102C>G p.T701S (on ENST00000359785 / NM_001193431.2; = p.T646S on NM_012411.5) | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100703360; called by muse, mutect2, varscan2
- PTPRM | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100154546; called by muse, mutect2, varscan2
- RARG | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100553259; called by muse, mutect2, varscan2
- RASEF | c.1477G>T p.D493Y | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV100906760; called by muse, mutect2, varscan2
- RBM5 | c.383A>C p.D128A | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100762115; called by muse, mutect2, varscan2
- RBM5 | c.795A>G p.I265M | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100762116, COSV61739359; called by muse, mutect2, varscan2
- RPGR | c.116A>G p.H39R | Missense Mutation (SNP) | VAF 231/519 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100139522; called by muse, mutect2, varscan2
- RPS6KA5 | c.2011G>T p.D671Y | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100002019, COSV56222285; called by muse, mutect2, varscan2
- SACS | c.1427G>A p.S476N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.613); catalogued as COSV101207146, COSV101207435; called by muse, mutect2, varscan2
- SALL1 | c.1003A>T p.S335C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV99171523; called by muse, mutect2, varscan2
- SDC3 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); catalogued as rs1472287835, COSV100232081; called by muse, mutect2, varscan2
- SGCE | c.541A>T p.N181Y (on ENST00000647096; = p.N145Y on NM_003919.3) | Missense Mutation (SNP) | VAF 71/292 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV99722082; called by muse, mutect2, varscan2
- SIRPB1 | c.805A>G p.N269D | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV99498140; called by muse, mutect2, varscan2
- SLC12A5 | c.536A>G p.N179S (on ENST00000454036 / NM_001134771.2; = p.N156S on NM_020708.5) | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99715224; called by muse, mutect2, varscan2
- SLMAP | c.1259G>C p.S420T (on ENST00000428312 / NM_001377924.1; = p.S441T on NM_007159.5) | Missense Mutation (SNP) | VAF 117/382 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV99065891, COSV99907961; called by muse, mutect2, varscan2
- SMARCA2 | c.3457-2A>T p.X1153_splice | Splice Site (SNP) | VAF 100/303 reads (33%) | catalogued as COSV100570192; called by muse, mutect2, varscan2
- SMYD4 | c.1339G>T p.V447F | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100562907; called by muse, mutect2, varscan2
- SPECC1L | c.3172A>T p.I1058F | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100061624; called by muse, mutect2, varscan2
- SPHKAP | c.4948A>G p.R1650G (on ENST00000392056 / NM_001142644.2; = p.R1621G on NM_030623.3) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV100763640; called by muse, mutect2, varscan2
- SPTBN2 | c.3777-2A>T p.X1259_splice | Splice Site (SNP) | VAF 27/91 reads (30%) | catalogued as COSV100018037; called by muse, mutect2, varscan2
- STAT3 | c.1919A>T p.Y640F | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.988); catalogued as rs769031989, COSV52882807; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SYCP2 | c.4276G>T p.E1426* | Nonsense Mutation (SNP) | VAF 89/433 reads (21%) | catalogued as COSV100697931, COSV62768998; called by muse, mutect2, varscan2
- SYS1 | c.434A>T p.E145V | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV99713770; called by muse, mutect2, varscan2
- TET1 | c.5371A>T p.N1791Y | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as COSV101017525; called by muse, mutect2, varscan2
- TEX2 | c.933A>T p.E311D | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV99366733; called by muse, mutect2, varscan2
- TGM4 | c.561T>A p.N187K | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as rs142027211; called by muse, mutect2, varscan2
- THAP3 | c.74+1G>T p.X25_splice | Splice Site (SNP) | VAF 21/51 reads (41%) | catalogued as COSV99275398; called by muse, mutect2, varscan2
- TLN2 | c.6194T>A p.L2065Q | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.871); catalogued as COSV100167891; called by muse, mutect2, varscan2
- TMEM128 | c.181G>T p.V61F (on ENST00000382753 / NM_001297552.2; = p.V37F on NM_032927.3) | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV99631856; called by muse, mutect2, varscan2
- TMPRSS2 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100151082; called by muse, mutect2, varscan2
- TNS2 | c.2989G>T p.D997Y (on ENST00000314250 / NM_170754.4; = p.D1007Y on NM_015319.2) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV100036538; called by muse, mutect2, varscan2
- TOP2A | c.2629A>T p.R877W | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV101396006; called by muse, mutect2, varscan2
- TPRX1 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.371); catalogued as COSV100445463; called by muse, mutect2, varscan2
- TTBK1 | c.1987G>A p.V663M | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.496); catalogued as COSV52491214, COSV99443608; called by muse, mutect2, varscan2
- ULK4 | c.259A>C p.I87L | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.187); catalogued as COSV100089987; called by muse, mutect2, varscan2
- USF3 | c.1187del p.N396Mfs*19 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | catalogued as COSV57069851; called by mutect2, pindel, varscan2
- UXS1 | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV51678559; called by muse, mutect2, varscan2
- VIPR2 | c.1259A>T p.Q420L | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV100056453; called by muse, mutect2, varscan2
- VN1R2 | c.953T>A p.L318H | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100447760; called by muse, mutect2, varscan2
- WWC1 | c.591-2A>T p.X197_splice | Splice Site (SNP) | VAF 42/116 reads (36%) | catalogued as COSV99514113; called by muse, mutect2, varscan2
- ZC3H18 | c.365A>T p.E122V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.678); catalogued as COSV99963794; called by muse, mutect2, varscan2
- ZDHHC16 | c.571T>A p.C191S | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100512649; called by muse, mutect2, varscan2
- ZEB1 | c.3303A>T p.Q1101H | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as COSV100313551; called by muse, mutect2, varscan2
- ZNF350 | c.715T>A p.C239S | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99702328; called by muse, mutect2
- ZNF365 | c.913A>T p.S305C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV101237934; called by muse, mutect2, varscan2
- ZNF512B | c.1510A>G p.I504V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs752638241, COSV99411175; called by muse, mutect2, varscan2
- ZNF649 | c.733A>C p.K245Q | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.131); catalogued as COSV100030697; called by muse, mutect2, varscan2
- ZNF804A | c.1322C>G p.S441* | Nonsense Mutation (SNP) | VAF 82/295 reads (28%) | catalogued as COSV56472586; called by muse, mutect2, varscan2
- ANXA13 | c.951_*6del | Nonstop Mutation (DEL) | VAF 17/103 reads (17%) | called by mutect2, pindel, varscan2
- ARHGEF35 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- BTAF1 | c.233del p.P78Qfs*24 | Frame Shift Del (DEL) | VAF 49/199 reads (25%) | called by mutect2, pindel, varscan2
- CC2D2A | c.1158del p.K386Nfs*9 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- CENPF | c.3690_3691del p.K1231Gfs*6 | Frame Shift Del (DEL) | VAF 340/888 reads (38%) | called by pindel, varscan2
- CFAP74 | c.2068A>T p.S690C | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- FFAR4 | c.706_712del p.H236Wfs*7 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | called by mutect2, pindel, varscan2
- GPR179 | c.3587C>T p.A1196V (on ENST00000621958; = p.A1195V on NM_001004334.4) | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MAGEB6B | c.622A>T p.K208* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- NME6 | c.364_365del p.T122* (on ENST00000415053; = p.T130* on NM_005793.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/104 reads (29%) | called by mutect2, pindel, varscan2
- ROBO1 | c.4838del p.G1613Efs*10 | Frame Shift Del (DEL) | VAF 54/227 reads (24%) | called by mutect2, pindel, varscan2
- TPTE | c.1066T>C p.S356P (on ENST00000618007 / NM_199261.4; = p.S338P on NM_199259.4) | Missense Mutation (SNP) | VAF 58/536 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- XPNPEP1 | c.1613dup p.L538Ffs*5 | Frame Shift Ins (INS) | VAF 25/113 reads (22%) | called by mutect2, pindel, varscan2
- ABHD2 | c.24C>T p.P8= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as rs779284661, COSV100756138; called by muse, mutect2, varscan2
- ACHE | c.1128C>T p.G376= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs1308868818, COSV99573678; called by muse, mutect2, varscan2
- ADAMTS2 | c.3330T>A p.P1110= | Silent (SNP) | VAF 50/279 reads (18%) | catalogued as COSV99280724; called by muse, mutect2, varscan2
- ADGRB2 | c.333G>T p.R111= | Silent (SNP) | VAF 44/153 reads (29%) | catalogued as COSV99925616; called by muse, mutect2, varscan2
- ADGRV1 | c.3204A>G p.R1068= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as COSV101315400; called by muse, mutect2, varscan2
- ARHGEF9 | c.228C>T p.P76= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV53638596, COSV53640200; called by muse, mutect2, varscan2
- CD44 | c.804T>A p.S268= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as COSV99555383; called by muse, mutect2, varscan2
- COG1 | c.1695C>G p.T565= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs760702621, COSV100245095, COSV55431178; called by muse, mutect2, varscan2
- COMMD3 | c.66C>T p.S22= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as rs940556387, COSV100936283; called by muse, mutect2, varscan2
- CSPG4 | c.6486T>G p.T2162= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100413317; called by muse, mutect2, varscan2
- DLEC1 | c.3879C>T p.T1293= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100341363; called by muse, mutect2, varscan2
- DUOX1 | c.294G>A p.L98= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as COSV99972741; called by muse, mutect2, varscan2
- EHBP1L1 | c.1410C>T p.T470= | Silent (SNP) | VAF 34/147 reads (23%) | catalogued as COSV100499604; called by muse, mutect2, varscan2
- EPHA6 | c.1206T>G p.S402= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs758462964, COSV101060725; called by muse, mutect2, varscan2
- ERC1 | c.195C>T p.A65= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs745971025, COSV100705596; called by muse, mutect2, varscan2
- FANCM | c.3099A>G p.K1033= | Silent (SNP) | VAF 46/143 reads (32%) | catalogued as COSV99950359; called by muse, mutect2, varscan2
- FGF19 | c.198C>A p.G66= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV99594248; called by muse, mutect2, varscan2
- FGFR1 | c.2271C>T p.I757= (on ENST00000447712 / NM_023110.3; = p.I755= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as rs369782405, COSV58335590; called by muse, mutect2, varscan2
- GALNT3 | c.933G>A p.L311= | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as COSV101204873; called by muse, mutect2, varscan2
- GBF1 | c.84C>A p.T28= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as COSV100890284; called by muse, mutect2, varscan2
- GJA3 | c.393G>A p.S131= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs749070481, COSV99576245; called by muse, mutect2, varscan2
- GOPC | c.1386T>C p.Y462= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs1263361191; called by muse, mutect2, varscan2
- IGKV3D-15 | c.69G>T p.V23= | Silent (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- IRX4 | c.510C>T p.P170= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as rs1420059343, COSV99180761; called by muse, mutect2
- KALRN | c.4350A>G p.P1450= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV99561913; called by muse, mutect2, varscan2
- KCND1 | c.594G>A p.V198= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as COSV99501676; called by muse, mutect2, varscan2
- MAP4K2 | c.1686G>T p.R562= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV99580199; called by muse, mutect2, varscan2
- MMP20 | c.63T>C p.T21= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV99497357; called by muse, mutect2, varscan2
- MUC16 | c.18954T>A p.T6318= | Silent (SNP) | VAF 52/130 reads (40%) | catalogued as COSV101197866; called by muse, mutect2, varscan2
- MUC20 | c.1314G>T p.G438= | Silent (SNP) | VAF 49/279 reads (18%) | catalogued as COSV100290879; called by muse, mutect2
- NR4A3 | c.1377T>A p.T459= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as rs529277354, COSV58246084; called by muse, mutect2, varscan2
- OXR1 | c.2061A>T p.I687= (on ENST00000442977 / NM_001198532.1; = p.I659= on NM_018002.3) | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as COSV99860721; called by muse, mutect2, varscan2
- PANK3 | c.1011A>C p.A337= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as rs752386767, COSV99496166; called by muse, mutect2, varscan2
- PDGFRA | c.1887A>G p.L629= | Silent (SNP) | VAF 34/130 reads (26%) | catalogued as rs1391798182, COSV99955327; called by muse, mutect2, varscan2
- PIAS2 | c.1605A>G p.P535= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV100244972; called by muse, mutect2, varscan2
- POLM | c.480G>C p.L160= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV99641627; called by muse, mutect2, varscan2
- PRG4 | c.72T>G p.S24= | Silent (SNP) | VAF 65/123 reads (53%) | catalogued as COSV100825592; called by muse, mutect2, varscan2
- PROX2 | c.1272T>A p.A424= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV101507785; called by muse, mutect2, varscan2
- PTPRD | c.546T>C p.S182= | Silent (SNP) | VAF 38/812 reads (5%) | catalogued as COSV100643078; called by muse, mutect2
- PTPRS | c.1494C>T p.T498= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs765834722, COSV53608681, COSV99508871; called by muse, mutect2, varscan2
- PTPRS | c.1065C>T p.G355= | Silent (SNP) | VAF 52/124 reads (42%) | catalogued as COSV99508872; called by muse, mutect2, varscan2
- S1PR4 | c.385C>T p.L129= | Silent (SNP) | VAF 27/148 reads (18%) | catalogued as COSV99858900; called by muse, mutect2, varscan2
- SEC31B | c.2538A>T p.A846= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV100947194; called by muse, mutect2, varscan2
- SGK1 | c.984G>T p.L328= | Silent (SNP) | VAF 53/182 reads (29%) | catalogued as COSV99397656; called by muse, varscan2
- SPRYD3 | c.1164A>T p.I388= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs778052180, COSV100036539; called by muse, mutect2, varscan2
- SPTBN4 | c.3366A>T p.L1122= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100149877; called by muse, mutect2
- SSR2 | c.30T>G p.A10= | Silent (SNP) | VAF 26/170 reads (15%) | catalogued as COSV99828497; called by muse, mutect2, varscan2
- ST18 | c.933T>G p.A311= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as COSV99387975; called by muse, mutect2, varscan2
- STK19 | c.441C>T p.R147= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV100514524; called by muse, mutect2, varscan2
- TECPR2 | c.1335C>T p.N445= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs778115838, COSV100849786; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTI1 | c.105A>T p.T35= | Silent (SNP) | VAF 51/109 reads (47%) | catalogued as COSV100989556; called by muse, mutect2, varscan2
- UPK1B | c.225A>G p.L75= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as COSV99953479; called by muse, mutect2, varscan2
- ZMAT1 | c.1113A>T p.S371= | Silent (SNP) | VAF 50/138 reads (36%) | catalogued as COSV100858652; called by muse, mutect2, varscan2
- ZNF622 | c.810C>T p.H270= | Silent (SNP) | VAF 45/156 reads (29%) | catalogued as rs1432545450, COSV100432974; called by muse, mutect2, varscan2
- ZNF808 | c.90T>C p.A30= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV100707759; called by muse, mutect2, varscan2
- AIFM1 | c.249+1279A>G | Intron (SNP) | VAF 14/269 reads (5%) | catalogued as COSV99780708; called by muse, mutect2
- MIR548I2 | n.100A>T | RNA (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- MIR9-1HG | n.289A>T | RNA (SNP) | VAF 13/118 reads (11%) | catalogued as COSV100023998; called by muse, mutect2
- TSPAN14 | chr10:80520664 A>T | 3'Flank (SNP) | VAF 34/107 reads (32%) | catalogued as COSV99627761; called by muse, mutect2, varscan2
- TTN | c.10361-3771A>T | Intron (SNP) | VAF 30/102 reads (29%) | catalogued as COSV100592216; called by muse, mutect2, varscan2
